Surgical pathology report (de-identified scan), TCGA case TCGA-DB-5279, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-5279-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

Brain, right frontal, excision: Grade 2 (of 4) oligodendroglioma (WHO grade II). See comment.

TCGA - DB - 5279

Comment: The tumor is moderately cellular and shows only scant mitotic activity. An old biopsy site with marked reactive changes is identified.

ADDENDA:

1p and 19q FISH studies were performed on cells within paraffin sections from tumor. Two hybridizations were performed: one with a 19q probe/control 19p pair and one with a 1p probe/control 1q pair. The 19q and 1p probes mapped to the regions that are commonly deleted in gliomas. The 19q to 19p probe ratio was 0.55. The 1p to 1q probe ratio was 0.56. For both probes, the normal ratio is approximately 1. Any ratio less than 0.80 is consistent with deletion of the chromosomal region of interest.

The results are abnormal and consistent with deletion of 1p and 19q. Approximately 46% of cells were apparently tetraploid but still had relative loss of 1p and 19q probe signals. Similar results have been observed in glioma specimens, especially oligodendrogliomas.

The test was developed and its performance characteristics determined by Laboratory Medicine and Pathology,

[page 2 of 2]
It has not been cleared or approved by the U.S. Food and Drug Administration, and is to be used as an adjunct to existing clinical and pathological information. This test does not rule out other chromosome anomalies.

Preliminary Frozen Section Consultation:

Brain, right frontal, excision: Glial tumor. Hold to further characterize this neoplasm.

Gross Description:

Tissue from the brain (right frontal--111.8 grams, 14.0 x 8.0 x 2.5 cm)

Block Summary:

Part A: RT.FRONTAL BRAIN TUMOR

- 1 rt frontal
- 2 rt frontal
- 3 rt frontal
- 4 rt frontal
- 5 rt frontal
- 6 rt frontal
- 7 rt frontal
- 8 rt frontal
- 9 rt frontal
- 10 rt frontal
- 11 rt frontal

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file 375e6072-b41d-4075-a2b4-16749e7eea63 (TCGA-DB-5279.74052AC9-36DE-45E7-8716-C3E74245D43D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).